Gene-level copy-number profile of tumor specimen C3L-01285-02 from CPTAC case C3L-01285, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 54.0 years (19,737 days).
Specimen C3L-01285-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 56cfb7f2-e92e-495a-ba4c-84c8b4a0ef1b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01285-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,754 have no estimate.
https://portal.gdc.cancer.gov/files/17358dd9-4c89-4f67-a3bb-dd6a1781f86c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 605; copy number 1: 3,013; copy number 2: 27,144; copy number 3: 10,296; copy number 4: 14,103; copy number 5: 2,570; copy number 6: 414; copy number 7: 236; copy number 8: 66; copy number 9: 130; copy number 11: 56; copy number 12: 101; copy number 15: 13; copy number 16: 43; copy number 22: 9; copy number 26: 8; copy number 30: 5; copy number 34: 12; copy number 37: 4; copy number 39: 5; copy number 59: 11; copy number 65: 23; copy number 70: 2.

Homozygous deletions (total copy number 0; autosomes only): 136 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–2): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr9:11,275,314–14,910,995, 38 genes (within-gene range 0–1): AL451129.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P.
- chr9:19,789,179–26,118,408, 91 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,708 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,724,512–1,745,992, 2 genes, copy number 5 (within-gene range 4–5): AL031282.1, SLC35E2A.
- chr1:25,242,249–25,338,213, 1 gene, copy number 5 (within-gene range 2–5): RSRP1.
- chr1:25,266,102–25,330,445, 3 genes, copy number 5: AL031432.2, RHD, SDHDP6.
- chr2:87,700,984–87,825,952, 4 genes, copy number 6: ANAPC1P4, PLGLB2, RGPD2, MTATP8P2.
- chr3:145,939,912–159,897,366, 246 genes, copy number 6–12 (broad region; genes not listed).
- chr3:177,816,865–185,980,872, 174 genes, copy number 5–59 (broad region; genes not listed).
- chr6:60,281,444–60,546,660, 1 gene, copy number 5: AC244258.1.
- chr7:98,846,488–99,325,826, 10 genes, copy number 5: TMEM130, TRRAP, MIR3609, AC004893.2, RNF14P3, SMURF1, AC004893.1, KPNA7, MYH16, AC004834.1.
- chr7:104,126,341–121,297,442, 207 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:12,043,506–12,115,516, 5 genes, copy number 5: DEFB131C, DEFB130B, RNA5SP253, DEFB108D, ZNF705D.
- chr8:36,784,324–141,002,216, 1,480 genes, copy number 5–9 (broad region; genes not listed).
- chr8:142,611,049–145,066,685, 158 genes, copy number 5 (broad region; genes not listed).
- chr9:61,581,813–61,662,690, 4 genes, copy number 5: AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr11:67,711,702–70,436,584, 87 genes, copy number 5–70 (broad region; genes not listed).
- chr11:80,653,429–81,556,425, 5 genes, copy number 9: ARL6IP1P3, LINC02720, AP003398.1, MTND4LP18, MTND6P25.
- chr12:66,767–37,576,384, 832 genes, copy number 5–6 (broad region; genes not listed).
- chr14:18,333,726–20,244,349, 101 genes, copy number 5 (broad region; genes not listed).
- chr14:21,723,713–22,506,702, 96 genes, copy number 5 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.
- chr15:20,516,252–20,520,627, 1 gene, copy number 8: AC023310.1.
- chr17:77,877,330–78,166,177, 10 genes, copy number 5: LINC01973, RNU1-80P, TNRC6C, AC015804.1, UBE2V2P2, RNU6-625P, TMC6, TMC8, C17orf99, EIF5AP2.
- chr18:45,034–6,415,237, 127 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr18:20,946,906–24,986,980, 90 genes, copy number 6–11 (within-gene range 2–11) (broad region; genes not listed).
- chr20:11,234,170–11,926,609, 10 genes, copy number 6–11: AL049649.1, RPS11P1, AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1.
- chr21:15,928,296–16,645,467, 1 gene, copy number 7 (within-gene range 4–7): MIR99AHG.
- chr21:16,284,696–19,900,043, 52 genes, copy number 6–7: SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1, AF212831.1, NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1, AP000432.2, C21orf91-OT1, C21orf91, AL109761.1, CHODL-AS1, RPL37P3, CHODL, AF130417.1, TMPRSS15, AL109763.1, MIR548XHG, AF240627.1, MIR548X, PPIAP22, AL157359.3, AL157359.2, AL157359.1, AP000431.2, AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P, RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1, LINC01683.

Autosomal genes at a single copy (total copy number 1): 1,427. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
